CCDI case PBBYIM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/e2024c41-43b3-4cd0-b733-04ef1d792d38

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 3.9 years (1,440 days).

Biospecimens (3 samples)
- Sample 0DUXNT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUXOF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUXOX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
